Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7646, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7646-01A (Primary Tumor).

[page 1 of 3]
ORIGINAL REPORT

SPECIMEN:

- A: Body of pancreas
- B: Gallbladder
- C: Bile duct margin
- D: Pancreas margin
- E: Portal vein
- F: Pancreas, duodenum, and jejunum
- G: Pancreatic margin
- H: Peripancreas

CLINICAL HISTORY:

Adenocarcinoma of pancreas and duodenum

DIAGNOSIS:

- A: BODY OF PANCREAS, BIOPSY:
- SMALL FRAGMENTS OF DENSE FIBROUS TISSUE. NO NORMAL PANCREATIC TISSUE PRESENT.
- B: GALLBLADDER, CHOLECYSTECTOMY:
- UNREMARKABLE GALLBLADDER. NEGATIVE FOR MALIGNANCY.
- C: BILE DUCT MARGIN, BIOPSY:
- NEGATIVE FOR MALIGNANCY.
- D: PANCREATIC MARGIN, BIOPSY:
- POSITIVE FOR ADENOCARCINOMA.
- E: PORTAL VEIN, BIOPSY:
- NEGATIVE FOR MALIGNANCY.
- F: PANCREAS, DUODENUM AND JEJUNUM, PARTIAL RESECTION:
- MODERATELY DIFFERENTIATED INVASIVE ADENOCARCINOMA, 4.5 CM.
- CENTERED IN PANCREATIC HEAD AND FOCALLY INVOLVING THE PANCREATIC RESECTION MARGIN.
- EVIDENCE OF EXTRAPANCREATIC FAT INVASION.
- EVIDENCE OF PERINEURAL AND VASCULAR INVASION. ←
- SIX PERIPANCREATIC LYMPH NODES ARE ALL POSITIVE FOR METASTATIC ADENOCARCINOMA WITH EXTRANODAL EXTENSION.
- TUMOR INVADING MUSCULAR WALL OF DUODENUM AND COMMON BILE DUCT.

FINAL

[page 2 of 3]
HISTOPATHOLOGY REPORT

GROSS DESCRIPTION:

0.3 x 0.2 cm. All tissue is submitted for QS in E. [REDACTED]

The frozen section cassette is resubmitted. [REDACTED]

P: The specimen consists of a pancreatic head (7.0 x 5.0 x 2.0 cm), common bile duct (5.0 cm in length and 2.5 cm in circumference), part of the distal stomach (3.0 cm in length and 8.0 cm in circumference), and duodenum and small bowel (22.0 cm in length and 6.0 cm in circumference). The pancreatic resection margin is painted black. Serial sections through the pancreatic head reveals an ill-defined firm mass lesion located within the pancreatic head. This lesion measures about 4.5 cm in greatest dimension. The lesion appears to be present at the inked pancreatic and resection margin and appears to invade the common bile duct grossly. The mucosa of the distal stomach and duodenum, as well as the small bowel are unremarkable.

Sections are submitted as follows:

- F1 - common bile duct resection margin.
- F2 through F5 - representative sections of the pancreatic head mass lesion with closest pancreatic resection margin.
- F6 and F7 - representative sections of the mass lesion with adjacent common bile duct.
- F8 - representative section of the ampulla.
- F9 - representative perpendicular section of gastric resection margin.
- F10 - perpendicular section of distal small bowel resection margin.
- F11 and F12 - one bisected peripancreatic lymph node.
- F13 and F14 - four possible peripancreatic lymph nodes (2 each).
- F15 - representative section of the mass lesion with adjacent duodenal mucosa.

Also present in the container is a segment of omentum measuring 25.0 x 10.0 x 2.0 cm. There is no obvious nodular lesion present. Two representative hemorrhagic areas are submitted in F16.

G: The specimen consists of a piece of soft tissue. All tissue submitted for QS in one block. [REDACTED]

The frozen section cassette is resubmitted. [REDACTED]

FINAL

[page 3 of 3]
HISTOPATHOLOGY REPORT

GROSS DESCRIPTION:

The specimen consists of a fragment of nodular white soft tissue measuring 1.5 x 1.0 x 1.0 cm. The specimen is bisected and submitted in toto in H1 and H2.

FROZEN SECTION (MICROSCOPIC):

C. Inflammatory reactive changes present.

D. Features consistent with chronic pancreatitis.

FROZEN SECTION DIAGNOSIS:

- A. BODY OF PANCREAS:
FIBROCOLLAGENOUS TISSUE INCLUDING A LARGE DUCT.
NEGATIVE FOR MALIGNANCY.
- B. NO PANCREATIC PARENCHYMA INCLUDED IN THE SPECIMEN.
- C. BILE DUCT MARGIN:
NEGATIVE FOR MALIGNANCY.
- D. PANCREAS MARGIN:
POSITIVE FOR CARCINOMA.
- E. PORTAL VEIN:
NEGATIVE FOR MALIGNANCY.
- F. PANCREATIC MARGIN:
NEGATIVE FOR MALIGNANCY.

FINAL

Source: NCI Genomic Data Commons file 1b6910a3-cf6c-4c65-b41e-2536baae7ad4 (TCGA-IB-7646.CE071FE4-67C4-4C5B-9829-433597E36067.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).